Gene-level copy-number profile of tumor specimen TARGET-10-PATBNT-09A from TARGET case TARGET-10-PATBNT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,938 days).
Specimen TARGET-10-PATBNT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d46ec493-f407-52ea-95e3-9bc0e707043f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATBNT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 358 have no estimate.
https://portal.gdc.cancer.gov/files/a074a7ce-22dc-4e2a-a550-cbde47daf198

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 2,526; copy number 2: 57,692; copy number 3: 25; copy number 4: 5.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 145. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
